Somatic mutation profile of tumor specimen TARGET-30-PATSRD-01A (aliquot TARGET-30-PATSRD-01A-01D) from TARGET case TARGET-30-PATSRD, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 3.4 years (1,224 days).
Specimen TARGET-30-PATSRD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a0b1b427-eb8b-45de-8f1a-f00dd373f6a2.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATSRD-10A (Blood Derived Normal), aliquot TARGET-30-PATSRD-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1f0a6233-0e94-4570-9dc2-3187cfb4d709

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RORC | c.799C>A p.L267M | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV59096316; called by muse, mutect2, varscan2
- FCGBP | c.8172G>C p.R2724S | Missense Mutation (SNP) | VAF 40/420 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
